Somatic mutation profile of tumor specimen SM-JU34H (aliquot 7316UP-1405) from CPTAC case C621273, project CPTAC-3 (Colon — Epithelial Neoplasms, NOS). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Colon, NOS.
Specimen SM-JU34H: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15c8a6ec-b7cb-4628-bfdb-fbea9e326f4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105218 (Blood Derived Normal), aliquot 7316UP-1614-1105218; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebb06051-4a7f-44ea-b8bb-ba28806452bc

The open-access MAF lists 2,080 somatic variants for this specimen: 1,362 protein-altering or splice-affecting, 421 silent, 297 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 934, Silent 421, Frame Shift Del 252, Intron 142, Frame Shift Ins 75, 3'UTR 50, Nonsense Mutation 46, 5'UTR 39, RNA 34, Splice Region 27, Splice Site 18, 5'Flank 16.

Variants (750 of 2,080; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.1171del p.R391Vfs*12 | Frame Shift Del (DEL) | VAF 134/360 reads (37%) | catalogued as rs751404811, CM045926, CM138787; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 97/240 reads (40%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ARG1 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 119/325 reads (37%) | catalogued as rs104893944, CM993111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 88/192 reads (46%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 183/485 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCND3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 70/172 reads (41%) | hotspot (GDC flag); catalogued as COSV57828583; called by muse, mutect2, varscan2
- COL4A5 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 203/497 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886088, CM072961, CM920213, CM960349, COSV60370055; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 88/218 reads (40%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 186/434 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KMT2D | c.10740G>A p.Q3580= | Splice Region (SNP) | VAF 84/185 reads (45%) | catalogued as rs398123700; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 39/100 reads (39%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 118/302 reads (39%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LZTR1 | c.27del p.Q10Rfs*15 | Frame Shift Del (DEL) | VAF 142/398 reads (36%) | catalogued as rs587777613; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NEB | c.11601+6124C>T | Intron (SNP) | VAF 237/1667 reads (14%) | catalogued as rs1212374733; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAK3 | c.343C>T p.R115* (on ENST00000262836 / NM_001324328.2; = p.R100* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 128/369 reads (35%) | catalogued as rs780775497, COSV53279983; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 57/159 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SCN1A | c.4554dup p.P1519Tfs*18 (on ENST00000303395 / NM_001202435.3; = p.P1508Tfs*18 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 161/512 reads (31%) | catalogued as rs794726825; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC18A2 | c.711dup p.F238Lfs*7 | Frame Shift Ins (INS) | VAF 102/252 reads (40%) | catalogued as rs762879329; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 107/332 reads (32%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 49/102 reads (48%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA12 | c.6960C>T p.T2320= (on ENST00000272895 / NM_173076.3; = p.T2002= on NM_015657.3) | Splice Region (SNP) | VAF 150/403 reads (37%) | catalogued as rs1021345094, COSV55952672; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA9 | c.3338G>A p.G1113D | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376048173; called by muse, mutect2, varscan2
- ABCB11 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 195/495 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.961); catalogued as rs199841445, CM117170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 170/468 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 76/178 reads (43%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCG1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs772470306, COSV59202048; called by muse, mutect2, varscan2
- AC008397.2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1354369697; called by muse, mutect2, varscan2
- AC231657.3 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV100540123; called by muse, mutect2, varscan2
- ACACB | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs754505331; called by muse, mutect2, varscan2
- ACTL8 | c.290del p.P97Lfs*2 | Frame Shift Del (DEL) | VAF 65/201 reads (32%) | catalogued as rs1557449414; called by mutect2, pindel, varscan2
- ADAMTS20 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253174139, COSV67129756, COSV67135057; called by muse, mutect2, varscan2
- ADAMTS7 | c.3515C>T p.P1172L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66309397; called by muse, mutect2, varscan2
- ADAMTSL5 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100389280; called by muse, mutect2, varscan2
- ADCK1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 132/363 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs754148232, COSV53078568; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 37/88 reads (42%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRL2 | c.2853del p.K951Nfs*54 (on ENST00000370717 / NM_001366005.1; = p.K938Nfs*54 on NM_012302.4) | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as COSV54672325; called by mutect2, pindel, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 59/124 reads (48%) | catalogued as rs1554870245; called by mutect2, varscan2
- ADSS1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 154/329 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200568797; called by muse, mutect2, varscan2
- AEBP1 | c.2841C>A p.N947K | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56261731, COSV99788811; called by muse, mutect2, varscan2
- AEBP2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 100/273 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs982709279; called by muse, varscan2
- AFF3 | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760333652, COSV57842263; called by mutect2, varscan2
- AGGF1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 95/303 reads (31%) | catalogued as rs376959475; called by muse, mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 81/236 reads (34%) | catalogued as rs748399150; called by mutect2, varscan2
- AGRN | c.5264C>T p.T1755I | Missense Mutation (SNP) | VAF 54/451 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs1378784269; called by muse, mutect2, varscan2
- AHNAK | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs540814813; called by muse, mutect2, varscan2
- AJAP1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); catalogued as COSV65450662, COSV65451766; called by muse, mutect2, varscan2
- AK5 | c.1549C>T p.R517C (on ENST00000354567 / NM_174858.3; = p.R491C on NM_012093.4) | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs144951885; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP11 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 127/418 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs949131444; called by muse, mutect2, varscan2
- AL133500.1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT tolerated (0.23); catalogued as rs368985442; called by muse, mutect2, varscan2
- ALAD | c.683del p.P228Lfs*24 | Frame Shift Del (DEL) | VAF 187/562 reads (33%) | catalogued as rs1564369378; called by mutect2, pindel, varscan2
- AMIGO2 | c.1271G>A p.C424Y | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56973924; called by muse, mutect2, varscan2
- AMPD2 | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 235/544 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56647784; called by muse, mutect2, varscan2
- ANGEL2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs190621865, COSV100853948; called by muse, mutect2, varscan2
- ANK1 | c.1717del p.L573Cfs*64 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | catalogued as CD014448; called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1018081322; called by muse, mutect2
- ANKMY1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 230/627 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs373716544; called by muse, mutect2, varscan2
- ANKRD62 | c.1439del p.K480Sfs*5 | Frame Shift Del (DEL) | VAF 40/111 reads (36%) | catalogued as rs774510795; called by mutect2, varscan2
- ANKS1A | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs764196187; called by muse, mutect2, varscan2
- ANKS3 | c.1805del p.P602Qfs*14 | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | catalogued as rs1325626781; called by mutect2, varscan2
- AP1M2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs781427984, COSV51569707; called by muse, mutect2, varscan2
- AP2A1 | c.2551dup p.Q851Pfs*55 | Frame Shift Ins (INS) | VAF 45/137 reads (33%) | catalogued as rs1555794627; called by mutect2, varscan2
- AP3S1 | c.380del p.G127Efs*8 | Frame Shift Del (DEL) | VAF 52/174 reads (30%) | catalogued as rs1253149765; called by mutect2, pindel, varscan2
- APBA2 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 172/483 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68788804; called by muse, mutect2, varscan2
- ARHGEF1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 120/307 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782497331, COSV61526594; called by muse, mutect2, varscan2
- ARHGEF12 | c.4229G>A p.R1410H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs202128571; called by muse, mutect2, varscan2
- ARHGEF17 | c.6127G>A p.G2043S | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs368547430; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 75/306 reads (25%) | catalogued as COSV61389445; called by pindel, varscan2*
- ARID1B | c.1243del p.A415Pfs*15 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs1417035592; called by mutect2, pindel, varscan2
- ARID2 | c.2554C>T p.Q852* | Nonsense Mutation (SNP) | VAF 107/257 reads (42%) | catalogued as rs925229355; called by muse, mutect2, varscan2
- ARMC4 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV59466905; called by muse, mutect2, varscan2
- ARRB1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs776740350, COSV63576778; called by muse, mutect2, varscan2
- ARSD | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54198845; called by muse, mutect2, varscan2
- ARSK | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.623); catalogued as rs374366998; called by muse, mutect2, varscan2
- ASB18 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749930126, COSV58236116; called by muse, mutect2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP8A1 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 114/310 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52534138; called by muse, varscan2
- AXDND1 | c.301T>C p.W101R | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773761120, COSV62645212, COSV62648726; called by muse, mutect2, varscan2
- B3GAT1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs965181801; called by muse, mutect2, varscan2
- B3GNTL1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762230226, COSV57946545; called by muse, mutect2
- BAG2 | c.222C>T p.D74= | Splice Region (SNP) | VAF 65/138 reads (47%) | catalogued as rs756825488, COSV65786799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCKDK | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 137/347 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.409); catalogued as rs374568685; called by muse, mutect2, varscan2
- BCL7C | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 143/358 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53062710; called by muse, mutect2, varscan2
- BCL9L | c.4388del p.P1463Rfs*94 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | catalogued as rs1555172524; called by mutect2, pindel, varscan2
- BCLAF1 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs749172270, COSV50357499, COSV99219398; called by muse, mutect2, varscan2
- BDNF | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 227/512 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs750030464, COSV100151992, COSV59234276; called by muse, mutect2, varscan2
- BEND7 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 134/292 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs767454294, COSV61987407; called by muse, mutect2, varscan2
- BEST3 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as rs1272134837, COSV58935261; called by muse, mutect2, varscan2
- BICDL2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV54157477; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2042A>C p.D681A | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100863735; called by muse, mutect2, varscan2
- BLVRA | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 161/393 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as rs1315965538; called by muse, mutect2, varscan2
- BRAF | c.2405C>T p.A802V (on ENST00000288602 / NM_001374244.1; = p.A762V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/367 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs775889922, COSV56115442, COSV56368837; called by muse, mutect2, varscan2
- BRD7 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs150539401; called by muse, mutect2, varscan2
- BRINP1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.949); catalogued as rs766334960, COSV56303151; called by muse, mutect2, varscan2
- BRWD3 | c.4573G>A p.G1525S | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs771173711, COSV64752792; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 88/229 reads (38%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- BUB3 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs1445770507; called by muse, mutect2, varscan2
- C3orf49 | c.620del p.K207Rfs*14 | Frame Shift Del (DEL) | VAF 78/252 reads (31%) | catalogued as rs1466063805; called by mutect2, varscan2
- C4orf54 | c.4640del p.P1547Qfs*70 | Frame Shift Del (DEL) | VAF 44/116 reads (38%) | catalogued as rs763082793; called by mutect2, pindel, varscan2
- C6orf163 | c.174dup p.E59Rfs*19 | Frame Shift Ins (INS) | VAF 36/95 reads (38%) | catalogued as rs1184371126; called by mutect2, pindel, varscan2
- C8A | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 232/526 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs149254627; called by muse, mutect2, varscan2
- CACNG3 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50064973; called by muse, mutect2, varscan2
- CALD1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs1355257511; called by muse, mutect2
- CALHM2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 183/443 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1278152148; called by muse, mutect2, varscan2
- CAMK2B | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 98/282 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); catalogued as COSV51663002; called by muse, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CATSPER1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs137878849; called by muse, mutect2, varscan2
- CAVIN3 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.106); catalogued as rs1475063142; called by muse, mutect2, varscan2
- CCDC115 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 105/255 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs752919660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC166 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1262427244; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 48/134 reads (36%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC189 | c.526dup p.C176Lfs*38 | Frame Shift Ins (INS) | VAF 36/112 reads (32%) | catalogued as rs749276025; called by mutect2, pindel
- CCDC58 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 118/351 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV52246521; called by muse, mutect2, varscan2
- CCDC85A | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.352); catalogued as rs757348777; called by muse, mutect2, varscan2
- CCNY | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1473002179; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | catalogued as rs780034402; called by mutect2, varscan2
- CD248 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as rs751114440, COSV60936700; called by muse, mutect2, varscan2
- CD40LG | c.429del p.G144Dfs*5 | Frame Shift Del (DEL) | VAF 115/326 reads (35%) | catalogued as CD050480; called by mutect2, pindel, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 106/317 reads (33%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CDC42BPA | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs146827361; called by muse, mutect2, varscan2
- CDH13 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs376202554; called by muse, mutect2, varscan2
- CDK8 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 142/518 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV67419126; called by muse, mutect2, varscan2
- CDNF | c.493dup p.T165Nfs*2 | Frame Shift Ins (INS) | VAF 106/341 reads (31%) | catalogued as rs1245164692; called by mutect2, pindel, varscan2
- CDRT15L2 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.302); catalogued as rs1257262707; called by muse, mutect2, varscan2
- CELF2 | c.1477C>T p.R493C (on ENST00000416382 / NM_001025077.3; = p.R506C on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59976730; called by muse, mutect2, varscan2
- CELSR1 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 195/431 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs147651051; called by muse, mutect2, varscan2
- CEMIP | c.1086+2T>G p.X362_splice | Splice Site (SNP) | VAF 158/433 reads (36%) | catalogued as COSV99586769; called by muse, mutect2, varscan2
- CEP164 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV54041370; called by muse, mutect2, varscan2
- CEP250 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.59); catalogued as rs750018459; called by muse, mutect2, varscan2
- CERT1 | c.766C>T p.R256C (on ENST00000405807 / NM_001130105.1; = p.R128C on NM_005713.3) | Missense Mutation (SNP) | VAF 88/250 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1214748516, COSV54657657; called by muse, mutect2, varscan2
- CFAP46 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 115/337 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs536559191, COSV100886078; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | catalogued as rs1274191949; called by mutect2, varscan2
- CHAF1A | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs758651234; called by muse, mutect2, varscan2
- CHD4 | c.2562G>T p.W854C (on ENST00000357008 / NM_001363606.2; = p.W867C on NM_001273.5) | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58909469; called by muse, mutect2, varscan2
- CHD5 | c.5444C>T p.T1815M | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs573215215, COSV52409305; called by muse, mutect2, varscan2
- CHD7 | c.6193C>T p.R2065C | Missense Mutation (SNP) | VAF 198/470 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM117687, CM133772, CM147861, COSV101418091; called by muse, mutect2, varscan2
- CHRNB3 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51493338; called by muse, mutect2, varscan2
- CHST5 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1410066549; called by muse, varscan2
- CKB | c.431dup p.H145Afs*77 | Frame Shift Ins (INS) | VAF 110/331 reads (33%) | catalogued as rs749928387; called by mutect2, pindel, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 74/190 reads (39%) | catalogued as rs761731080; called by mutect2, varscan2
- CLIC5 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.338); catalogued as COSV51754904; called by muse, mutect2, varscan2
- CLPTM1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV61613318; called by muse, mutect2, varscan2
- CLRN2 | c.435C>T p.G145= | Splice Region (SNP) | VAF 54/143 reads (38%) | catalogued as rs994079252; called by muse, mutect2
- CLSTN2 | c.2211C>T p.Y737= | Splice Region (SNP) | VAF 40/107 reads (37%) | catalogued as rs148317543; called by muse, mutect2, varscan2
- CNPY1 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1293036001; called by muse, mutect2, varscan2
- CNTN1 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 179/420 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs374471716; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP4 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 67/192 reads (35%) | catalogued as rs1013311455, COSV56671148; called by muse, mutect2, varscan2
- COL12A1 | c.5303G>A p.S1768N | Missense Mutation (SNP) | VAF 138/388 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs371310137; called by muse, mutect2, varscan2
- COL4A5 | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60358956; called by muse, mutect2, varscan2
- COL5A1 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs530442560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 154/474 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs751443853, COSV55195783; called by muse, mutect2, varscan2
- COL7A1 | c.8506G>A p.V2836I | Missense Mutation (SNP) | VAF 241/670 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1246764789; called by muse, mutect2, varscan2
- COL7A1 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 209/497 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs757643340, COSV60395303; called by muse, mutect2, varscan2
- COPG1 | c.1523G>A p.S508N | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.966); catalogued as rs778058395, COSV100135689; called by muse, mutect2, varscan2
- CORO2B | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs748303629; called by mutect2, varscan2
- COX4I2 | c.1-2A>G p.X1_splice | Splice Site (SNP) | VAF 188/423 reads (44%) | catalogued as rs1192963566; called by muse, mutect2, varscan2
- CPLANE1 | c.17G>T p.G6V (on ENST00000425232; = p.G78V on NM_023073.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554117507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPPED1 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 165/367 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.35); catalogued as COSV55497505; called by muse, mutect2, varscan2
- CPZ | c.1104G>A p.M368I (on ENST00000360986 / NM_001014447.3; = p.M357I on NM_003652.3) | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs866318508; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 282/716 reads (39%) | catalogued as rs747832403; called by mutect2, varscan2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 187/442 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CREB3L2 | c.851A>T p.K284I | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1403332874; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 21/38 reads (55%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYBG2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as rs369844437; called by muse, mutect2, varscan2
- CSNK1D | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 243/534 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs887426479; called by muse, mutect2, varscan2
- CUZD1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 122/362 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868328670, COSV59025861; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs772257590; called by mutect2, varscan2
- CXCR2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100578986; called by muse, mutect2, varscan2
- CYB5R2 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55085436; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 79/208 reads (38%) | catalogued as rs756254049; called by mutect2, varscan2
- CYP39A1 | c.270dup p.V91Sfs*4 | Frame Shift Ins (INS) | VAF 37/147 reads (25%) | catalogued as rs1225765844; called by mutect2, pindel, varscan2
- DCAF12L2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV63583165; called by muse, mutect2, varscan2
- DCAF8 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 159/363 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs752089736, COSV58783348; called by muse, mutect2, varscan2
- DDX20 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV63831144; called by muse, mutect2, varscan2
- DENND6B | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 143/328 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs749511894, COSV69806572; called by muse, mutect2, varscan2
- DGKQ | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 167/426 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1180775609; called by muse, mutect2, varscan2
- DHX34 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 152/404 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201148024, COSV60895322; called by muse, mutect2, varscan2
- DIP2A | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as rs369917913; called by muse, mutect2, varscan2
- DLC1 | c.1820C>T p.A607V (on ENST00000276297 / NM_001348081.2; = p.A170V on NM_006094.5) | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs929788084, COSV52326811; called by muse, mutect2, varscan2
- DLGAP1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759947491; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 28/247 reads (11%) | catalogued as rs762874947; called by mutect2, varscan2
- DLGAP4 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 155/397 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs192489219; called by muse, mutect2, varscan2
- DLGAP5 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV55964994; called by muse, mutect2, varscan2
- DMBX1 | c.740del p.G247Vfs*15 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | catalogued as COSV63601642, COSV63602450; called by mutect2, pindel
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 87/250 reads (35%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH10 | c.5963G>A p.R1988H (on ENST00000409039; = p.R1927H on NM_207437.3) | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs370827875; called by muse, mutect2, varscan2
- DNAH10 | c.8210C>T p.T2737M (on ENST00000409039; = p.T2676M on NM_207437.3) | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs756405690, COSV68989039; called by muse, mutect2, varscan2
- DNAH11 | c.11678C>T p.T3893M | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs763843747, COSV60974905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNM1 | c.2434del p.A812Rfs*76 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs747024881; called by mutect2, varscan2
- DNMT3A | c.176del p.P59Rfs*13 | Frame Shift Del (DEL) | VAF 64/146 reads (44%) | catalogued as COSV53040261; called by mutect2, varscan2
- DOCK11 | c.3290A>G p.Q1097R | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); catalogued as COSV52234969; called by muse, mutect2, varscan2
- DPP10 | c.1312dup p.I438Nfs*7 | Frame Shift Ins (INS) | VAF 30/105 reads (29%) | catalogued as rs752853990; called by mutect2, pindel, varscan2
- DRC7 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs778999719; called by muse, mutect2, varscan2
- DSEL | c.628dup p.I210Nfs*6 | Frame Shift Ins (INS) | VAF 91/307 reads (30%) | catalogued as rs1215181888; called by mutect2, pindel, varscan2
- DUOX2 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs750639157, COSV66535311; called by muse, mutect2, varscan2
- DUSP22 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 98/431 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV60527529; called by muse, mutect2, varscan2
- DYRK3 | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100895664; called by muse, mutect2, varscan2
- E2F7 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 111/278 reads (40%) | catalogued as rs780614837, COSV59739397; called by muse, mutect2, varscan2
- E4F1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs765015745, COSV57040679, COSV57041008; called by muse, mutect2, varscan2
- ECPAS | c.4681G>A p.G1561R | Missense Mutation (SNP) | VAF 103/309 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1367783816; called by muse, mutect2, varscan2
- EIF2B2 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 210/494 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs765712931; called by muse, mutect2, varscan2
- EIF4B | c.925T>C p.S309P | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs966204770, COSV100016697; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 69/190 reads (36%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EMILIN2 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs201283611; called by muse, mutect2, varscan2
- EPG5 | c.5704dup p.Y1902Lfs*2 | Frame Shift Ins (INS) | VAF 56/134 reads (42%) | catalogued as rs760768451; called by mutect2, varscan2
- EPHA10 | c.332A>C p.D111A | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100139897; called by muse, mutect2, varscan2
- EPHA8 | c.2735C>T p.P912L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs748668673; called by muse, mutect2, varscan2
- ERO1A | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs370745677, COSV67471492; called by muse, mutect2, varscan2
- ERVFRD-1 | c.266C>A p.A89E | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs758079525; called by muse, mutect2, varscan2
- ETS1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 163/417 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60096717; called by muse, mutect2, varscan2
- EVC2 | c.2221C>A p.L741I | Missense Mutation (SNP) | VAF 378/927 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV60401706; called by muse, mutect2, varscan2
- EXO1 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 141/417 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs750940919, COSV62218506; called by muse, mutect2, varscan2
- EXOSC10 | c.1587-3del | Splice Region (DEL) | VAF 14/128 reads (11%) | catalogued as rs1326388669; called by pindel, varscan2
- F8 | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 194/597 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM054679, CM1314155; called by muse, mutect2, varscan2
- FAM117B | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 262/666 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57419272; called by muse, mutect2, varscan2
- FAM124A | c.500A>G p.Y167C (on ENST00000322475 / NM_001242312.2; = p.Y203C on NM_145019.4) | Missense Mutation (SNP) | VAF 147/529 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs750587172; called by muse, mutect2, varscan2
- FAM135B | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52716667, COSV52755853; called by muse, mutect2, varscan2
- FAM155A | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 178/659 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs202062814, COSV65586584; called by muse, mutect2, varscan2
- FAM187A | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1453848416; called by muse, mutect2
- FAM189B | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 151/350 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.905); catalogued as rs1240159655, COSV63219355; called by muse, mutect2, varscan2
- FAM193B | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs373410343; called by muse, mutect2, varscan2
- FAM20A | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 174/468 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1335379646; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 93/215 reads (43%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 186/502 reads (37%) | catalogued as rs747011618; called by mutect2, varscan2
- FAT3 | c.8239C>T p.R2747W | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs200763217; called by muse, mutect2, varscan2
- FBXL7 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 149/391 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1401076306; called by muse, mutect2, varscan2
- FBXO30 | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52791293; called by muse, mutect2, varscan2
- FCGBP | c.9221A>T p.E3074V | Missense Mutation (SNP) | VAF 50/860 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs765893553; called by muse, mutect2
- FDFT1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as rs559977336; called by muse, mutect2, varscan2
- FERD3L | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs866406481, COSV51762348; called by muse, mutect2, varscan2
- FGF2 | c.17del p.G6Vfs*4 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs776164719; called by mutect2, pindel, varscan2
- FITM1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 135/341 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as rs900868217; called by muse, mutect2, varscan2
- FLT3LG | c.215del p.G72Afs*30 | Frame Shift Del (DEL) | VAF 67/171 reads (39%) | catalogued as COSV52619033, COSV52621079; called by mutect2, pindel, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 71/222 reads (32%) | catalogued as COSV56098414; called by mutect2, varscan2
- FN1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 206/510 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777763524, COSV100115678; called by muse, mutect2, varscan2
- FOXF2 | c.96del p.A33Pfs*89 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as COSV99453578; called by pindel, varscan2
- FOXL1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 257/607 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57213590; called by muse, mutect2, varscan2
- FOXN3 | c.1162G>A p.E388K (on ENST00000261302; = p.E366K on NM_005197.4) | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs772625675, COSV54305153; called by muse, mutect2, varscan2
- FRAS1 | c.5783A>G p.H1928R | Missense Mutation (SNP) | VAF 147/345 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as rs1471365312, COSV99356005; called by muse, mutect2, varscan2
- FREM3 | c.6398G>T p.S2133I | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as rs965688625; called by muse, mutect2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 62/174 reads (36%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSIP2 | c.8038del p.T2680Hfs*3 | Frame Shift Del (DEL) | VAF 68/176 reads (39%) | catalogued as rs755234663; called by mutect2, varscan2
- FSIP2 | c.20133A>T p.K6711N | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); catalogued as rs754643795; called by muse, mutect2, varscan2
- FSTL1 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99821095; called by muse, mutect2, varscan2
- FUT1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 198/517 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.891); catalogued as rs150995632; called by muse, mutect2, varscan2
- FZD2 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1339183245, COSV59527929; called by muse, mutect2, varscan2
- FZD9 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.005); catalogued as rs782003819; called by muse, mutect2, varscan2
- GAD1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 142/383 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as rs1238959934, COSV60151582; called by muse, mutect2
- GALNT14 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100204024; called by muse, mutect2, varscan2
- GALNT8 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 142/397 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs769100382, COSV52897296, COSV52900639; called by muse, mutect2, varscan2
- GART | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 100/215 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs757263290; called by muse, mutect2, varscan2
- GAS6 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750814570, COSV59853160; called by muse, mutect2, varscan2
- GASK1B | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56709593; called by muse, mutect2, varscan2
- GATA2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.434); catalogued as rs1413920280; called by muse, mutect2, varscan2
- GATAD2A | c.1094del p.P365Hfs*9 | Frame Shift Del (DEL) | VAF 144/389 reads (37%) | catalogued as rs35804366; called by mutect2, pindel, varscan2
- GCC1 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1335179556; called by muse, mutect2, varscan2
- GCK | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CD024177; called by muse, mutect2, varscan2
- GCN1 | c.3946C>T p.R1316* | Nonsense Mutation (SNP) | VAF 158/370 reads (43%) | catalogued as rs1283531605; called by muse, mutect2, varscan2
- GFRA1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 144/358 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs754335579; called by muse, mutect2, varscan2
- GLB1 | c.2006dup p.N669Kfs*53 | Frame Shift Ins (INS) | VAF 176/454 reads (39%) | catalogued as rs759633494; called by mutect2, varscan2
- GLI2 | c.4100G>A p.R1367H (on ENST00000361492 / NM_001374353.1; = p.R1384H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs763852684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI3 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 219/599 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270096533; called by muse, mutect2, varscan2
- GMIP | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs200618177; called by muse, mutect2, varscan2
- GNAL | c.854C>T p.A285V (on ENST00000269162 / NM_001142339.3; = p.A362V on NM_182978.4) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV52334956; called by muse, mutect2, varscan2
- GNAS | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 237/606 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs587778390, COSV58345123, COSV58347881; ClinVar: not provided; called by muse, mutect2, varscan2
- GNAZ | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1365180134, COSV50739124; called by muse, mutect2, varscan2
- GNB4 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 78/264 reads (30%) | catalogued as rs1252790676, COSV51709431; called by muse, mutect2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 49/126 reads (39%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGA6C | c.2036del p.P679Rfs*? | Frame Shift Del (DEL) | VAF 87/236 reads (37%) | catalogued as rs773221176, COSV100316303; called by mutect2, varscan2
- GPR174 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs200548821, CM136727; called by muse, mutect2, varscan2
- GPR6 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 372/920 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51573009; called by muse, mutect2, varscan2
- GRIK1 | c.812G>T p.R271M | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100518343; called by muse, mutect2, varscan2
- GRIN3B | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 140/321 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as rs79866475; called by muse, mutect2, varscan2
- GRM5 | c.3320C>T p.T1107M (on ENST00000305447 / NM_001143831.2; = p.T1075M on NM_000842.4) | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.966); catalogued as rs546269389; called by muse, mutect2, varscan2
- GRM6 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 284/756 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs369555190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRN | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 164/351 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as rs750483739; called by muse, mutect2, varscan2
- GSC | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 170/407 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99031944; called by muse, mutect2, varscan2
- GTPBP3 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 138/324 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs140393384; called by muse, mutect2, varscan2
- HDAC6 | c.3532G>A p.D1178N | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs782174981, COSV100491256; called by muse, mutect2, varscan2
- HDHD3 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs747591014, COSV53056601; called by muse, mutect2, varscan2
- HELLS | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371792267; called by muse, mutect2, varscan2
- HELZ2 | c.6727C>T p.R2243C (on ENST00000467148 / NM_001037335.2; = p.R1674C on NM_033405.3) | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636547; called by muse, mutect2, varscan2
- HERC2 | c.9089G>A p.S3030N | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.929); catalogued as rs201973387; called by muse, mutect2, varscan2
- HERC5 | c.418dup p.I140Nfs*19 | Frame Shift Ins (INS) | VAF 56/157 reads (36%) | catalogued as rs770854785; called by mutect2, varscan2
- HIGD1A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs565556493, COSV58414573, COSV58414971; called by muse, mutect2, varscan2
- HK3 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs745623940; called by muse, mutect2, varscan2
- HK3 | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs754406639; called by muse, mutect2, varscan2
- HLA-B | c.343+1G>A p.X115_splice | Splice Site (SNP) | VAF 30/238 reads (13%) | catalogued as rs1168937188, COSV69520345, COSV69521733; called by muse, varscan2
- HLA-B | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 308/451 reads (68%) | catalogued as rs776780353, COSV69520663, COSV69521156; called by muse, mutect2, varscan2
- HLA-DQB1 | c.535del p.I180Lfs*12 | Frame Shift Del (DEL) | VAF 56/160 reads (35%) | catalogued as rs751976368; called by mutect2, pindel, varscan2
- HLTF | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs372129397; called by muse, mutect2, varscan2
- HMCN2 | c.5063A>G p.E1688G | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs548738574; called by muse, mutect2, varscan2
- HMCN2 | c.5926C>T p.R1976W | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.535); catalogued as rs577965469; called by muse, mutect2, varscan2
- HOXD13 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 232/549 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763149315, COSV66832773; called by muse, mutect2, varscan2
- HRH2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 166/354 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199533; called by muse, mutect2, varscan2
- HS3ST1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 119/349 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as COSV50024246; called by muse, mutect2, varscan2
- HS6ST2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1428531182; called by muse, mutect2, varscan2
- HSPBP1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 165/429 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355096967; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 61/172 reads (35%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE1 | c.6476C>T p.A2159V | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs375797140; called by muse, mutect2, varscan2
- IDUA | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 181/441 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753308650; called by muse, mutect2, varscan2
- IGSF10 | c.5642G>A p.G1881D | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477022137; called by muse, mutect2, varscan2
- IL11 | c.540del p.L181Cfs*3 | Frame Shift Del (DEL) | VAF 136/411 reads (33%) | catalogued as COSV99214838; called by mutect2, pindel, varscan2
- IL18R1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV52125413; called by muse, mutect2, varscan2
- IL1B | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 206/544 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1312684514; called by muse, mutect2, varscan2
- ILVBL | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as rs1263662509; called by muse, mutect2, varscan2
- INHBA | c.802del p.E268Kfs*91 | Frame Shift Del (DEL) | VAF 65/184 reads (35%) | catalogued as COSV54219689, COSV54219996; called by mutect2, pindel, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INTS5 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.55); catalogued as rs756443040; called by muse, mutect2, varscan2
- IPO9 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1157160147, COSV64234766; called by muse, mutect2, varscan2
- IQSEC3 | c.565del p.V189Cfs*109 | Frame Shift Del (DEL) | VAF 88/283 reads (31%) | catalogued as COSV58283925; called by mutect2, pindel, varscan2
- IRS4 | c.1952del p.G651Efs*23 | Frame Shift Del (DEL) | VAF 241/663 reads (36%) | catalogued as COSV64532818; called by mutect2, pindel, varscan2
- IRX1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs976102129; called by muse, mutect2
- IRX6 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 187/416 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51860590; called by muse, mutect2, varscan2
- ITGB2 | c.2218G>A p.G740S (on ENST00000302347; = p.G716S on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 215/519 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1064794297, CM140872; called by muse, mutect2, varscan2
- ITIH1 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 59/150 reads (39%) | catalogued as rs757375117, COSV56255433; called by muse, mutect2, varscan2
- ITK | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 195/473 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs780522355, COSV68435348, COSV68435382; called by muse, mutect2, varscan2
- ITPKB | c.179dup p.A61Sfs*24 | Frame Shift Ins (INS) | VAF 61/171 reads (36%) | catalogued as rs1240487177; called by mutect2, pindel, varscan2
- JRK | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs375362605, COSV101401029; called by muse, mutect2, varscan2
- JRK | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 97/258 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1283928169, COSV70630291; called by muse, mutect2, varscan2
- JUND | c.252del p.D85Tfs*12 | Frame Shift Del (DEL) | VAF 76/201 reads (38%) | catalogued as rs1555702626, COSV53254483; called by mutect2, varscan2
- KBTBD13 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 113/291 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs775442274; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 132/336 reads (39%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNH8 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs747522897; called by muse, mutect2
- KCNJ4 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 152/384 reads (40%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs776902829; called by muse, mutect2, varscan2
- KIAA1109 | c.14227C>T p.R4743C | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767116983, COSV52662892; called by muse, mutect2, varscan2
- KIF4B | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 166/461 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs374852803; called by muse, mutect2, varscan2
- KLHDC3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.943); catalogued as rs962420421; called by muse, mutect2, varscan2
- KLHDC7A | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 201/426 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs185356965; called by muse, mutect2, varscan2
- KLHDC9 | c.387dup p.A130Rfs*5 | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs761803466; called by mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 33/134 reads (25%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL10 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs782043692; called by muse, mutect2, varscan2
- KLHL42 | c.1321_1325del p.N441Dfs*6 | Frame Shift Del (DEL) | VAF 169/504 reads (34%) | catalogued as rs774224353; called by mutect2, pindel, varscan2
- KMT2D | c.16086G>T p.K5362N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as CD159008, COSV99982182; called by muse, mutect2, varscan2
- KNL1 | c.5884C>T p.L1962F (on ENST00000346991 / NM_170589.5; = p.L1936F on NM_144508.5) | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs939715110, COSV61151691; called by muse, mutect2, varscan2
- KRT23 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 122/293 reads (42%) | catalogued as rs773310417; called by muse, mutect2, varscan2
- KRT75 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768683532; called by muse, mutect2, varscan2
- KRTAP10-11 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 226/520 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1555940261; called by muse, mutect2, varscan2
- LAMC3 | c.2336dup p.Q781Pfs*7 | Frame Shift Ins (INS) | VAF 55/153 reads (36%) | catalogued as rs765163533; called by mutect2, pindel, varscan2
- LARP4 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs986718590, COSV53321066; called by muse, mutect2, varscan2
- LARP4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs367566217; called by muse, mutect2, varscan2
- LDHD | c.1026A>G p.T342= | Splice Region (SNP) | VAF 77/178 reads (43%) | catalogued as rs769465289; called by muse, mutect2, varscan2
- LHB | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 246/618 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs551522078; called by muse, mutect2
- LHX3 | c.178G>A p.D60N (on ENST00000371748 / NM_178138.6; = p.D65N on NM_014564.5) | Missense Mutation (SNP) | VAF 222/473 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs146027009, COSV65583087; called by muse, mutect2, varscan2
- LHX5 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 106/233 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs748221055, COSV55663654; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 49/146 reads (34%) | catalogued as rs765287063; called by mutect2, varscan2
- LMTK3 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 96/265 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99540831; called by muse, varscan2
- LMTK3 | c.363C>T p.D121= | Splice Region (SNP) | VAF 38/82 reads (46%) | catalogued as rs1366358917; called by muse, mutect2, varscan2
- LOXL4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs369940076; called by muse, mutect2
- LRIT2 | c.1532dup p.A512Cfs*11 | Frame Shift Ins (INS) | VAF 31/95 reads (33%) | catalogued as rs1307233234; called by mutect2, pindel, varscan2
- LRRC53 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs1348693368; called by muse, mutect2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 94/246 reads (38%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LRRTM1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54443224; called by muse, mutect2, varscan2
- LTB4R2 | c.901C>T p.R301* (on ENST00000528054; = p.R270* on NM_019839.5) | Nonsense Mutation (SNP) | VAF 314/774 reads (41%) | catalogued as rs1338381164; called by muse, mutect2, varscan2
- LTN1 | c.2100del p.V701Sfs*5 | Frame Shift Del (DEL) | VAF 47/123 reads (38%) | catalogued as rs753955477; called by mutect2, pindel, varscan2
- LY86 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1343214658; called by muse, mutect2, varscan2
- LYAR | c.238-2A>G p.X80_splice | Splice Site (SNP) | VAF 77/154 reads (50%) | catalogued as rs752937370; called by muse, mutect2, varscan2
- LYZL6 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs766673424; called by muse, mutect2, varscan2
- MAN2B2 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as rs373139515; called by muse, mutect2, varscan2
- MAP1B | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs780650498, COSV57103118; called by muse, mutect2, varscan2
- MAP1LC3C | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 114/263 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs982683803; called by muse, mutect2, varscan2
- MAP3K9 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1220234795, COSV101173607; called by muse, mutect2
- MAST2 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs751193932; called by muse, mutect2, varscan2
- MBD2 | c.471dup p.G158Rfs*28 | Frame Shift Ins (INS) | VAF 43/132 reads (33%) | catalogued as rs755716804; called by mutect2, varscan2
- MCM5 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 141/389 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs200021712, COSV53346220, COSV99331765; called by muse, mutect2, varscan2
- MDGA1 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1561843973; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 132/336 reads (39%) | catalogued as rs773080349; called by mutect2, varscan2
- MEGF8 | c.5779C>T p.R1927C (on ENST00000251268 / NM_001271938.2; = p.R1860C on NM_001410.3) | Missense Mutation (SNP) | VAF 119/285 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs368438075; called by muse, mutect2, varscan2
- MEI1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs774663994; called by muse, mutect2, varscan2
- MEPCE | c.1595del p.G532Vfs*58 | Frame Shift Del (DEL) | VAF 75/249 reads (30%) | catalogued as COSV99440132; called by mutect2, pindel, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 113/261 reads (43%) | catalogued as rs745891632; called by mutect2, varscan2
- MEX3B | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752952352, COSV61663584; called by muse, mutect2, varscan2
- MID1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 162/401 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1483645727; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 98/262 reads (37%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINK1 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 88/241 reads (37%) | catalogued as COSV100767239; called by muse, mutect2, varscan2
- MMP28 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs751685683; called by muse, mutect2, varscan2
- MOB3A | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 155/385 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs199687461; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 90/242 reads (37%) | catalogued as rs755830405; called by mutect2, varscan2
- MPEG1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs200732824; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 124/364 reads (34%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRNIP | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs758236790, COSV52974593; called by muse, mutect2, varscan2
- MRPL24 | c.52dup p.H18Pfs*34 | Frame Shift Ins (INS) | VAF 45/165 reads (27%) | catalogued as rs760797871; called by mutect2, varscan2
- MRPS31 | c.739del p.R247Gfs*15 | Frame Shift Del (DEL) | VAF 135/532 reads (25%) | catalogued as COSV100062133; called by mutect2, pindel, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 79/232 reads (34%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MTF1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 163/427 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs773997656; called by muse, mutect2, varscan2
- MTM1 | c.963A>T p.L321F | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs782645058; called by muse, mutect2, varscan2
- MTUS2 | c.2595C>A p.S865R | Missense Mutation (SNP) | VAF 98/394 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs866505175; called by muse, mutect2, varscan2
- MUC16 | c.3397del p.M1133* | Frame Shift Del (DEL) | VAF 51/156 reads (33%) | catalogued as rs754876491; called by mutect2, pindel, varscan2
- MUC4 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1363380008; called by muse, mutect2, varscan2
- MUC5B | c.1982G>A p.C661Y | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762864911; called by muse, mutect2, varscan2
- MUC6 | c.6938C>T p.S2313L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367913682, COSV59962762; called by muse, mutect2, varscan2
- MVD | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 148/351 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs1425276990; called by muse, mutect2, varscan2
- MYB | c.1315C>A p.Q439K | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1476805948; called by muse, mutect2, varscan2
- MYBPC2 | c.2802del p.I937* | Frame Shift Del (DEL) | VAF 155/481 reads (32%) | catalogued as rs1368598634; called by mutect2, pindel, varscan2
- MYO1C | c.1252G>A p.G418R (on ENST00000648651 / NM_001080779.2; = p.G383R on NM_033375.5) | Missense Mutation (SNP) | VAF 256/619 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764101826; called by muse, mutect2, varscan2
- MYO1F | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as rs373423000; called by muse, mutect2, varscan2
- MYO3A | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs1339616970; called by muse, mutect2, varscan2
- N4BP2 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.054); catalogued as rs118012789; called by muse, mutect2, varscan2
- NAT8L | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 208/547 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs763623026; called by muse, mutect2, varscan2
- NCAPH2 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as rs200790371; called by muse, mutect2, varscan2
- NCOR2 | c.6460G>A p.A2154T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs368425851; called by mutect2, varscan2
- NDST1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 129/299 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as rs962700674; called by muse, mutect2, varscan2
- NFE2 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 229/579 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56457431; called by muse, mutect2, varscan2
- NFE2 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as rs772353922, COSV56456302, COSV56456725; called by muse, mutect2
- NIFK | c.859del p.R287Dfs*23 | Frame Shift Del (DEL) | VAF 176/468 reads (38%) | catalogued as COSV53535587; called by mutect2, pindel, varscan2
- NIN | c.4461G>T p.K1487N | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99812630; called by muse, mutect2, varscan2
- NIPBL | c.6111G>A p.T2037= | Splice Region (SNP) | VAF 19/185 reads (10%) | catalogued as rs755732764; called by muse, mutect2, varscan2
- NLGN2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1183734429; called by muse, mutect2, varscan2
- NOL4L | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs753607764, COSV62889711; called by muse, mutect2, varscan2
- NOTCH3 | c.6233G>A p.R2078Q | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as rs765403158, COSV54628708, COSV54639957; called by muse, varscan2
- NOVA1 | c.1234G>T p.G412* | Nonsense Mutation (SNP) | VAF 134/291 reads (46%) | catalogued as COSV99948426; called by muse, mutect2, varscan2
- NPBWR2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751123142, COSV63900540; called by muse, mutect2, varscan2
- NPHP3 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 179/430 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as rs781537576; called by muse, mutect2, varscan2
- NPPA | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778138090, COSV56738679, COSV56742702; called by muse, mutect2, varscan2
- NR1D1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs373443634, COSV52840970; called by muse, mutect2, varscan2
- NRDE2 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239535998; called by muse, mutect2, varscan2
- NRM | c.187del p.L63Wfs*23 | Frame Shift Del (DEL) | VAF 73/216 reads (34%) | catalogued as rs757081047; called by mutect2, pindel, varscan2
- NT5C1B | c.664C>T p.R222W (on ENST00000359846 / NM_001199086.2; = p.R162W on NM_033253.4) | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV58394824; called by muse, mutect2, varscan2
- NTRK3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 189/521 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs771206956, COSV58107419; called by muse, mutect2, varscan2
- NUDT18 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs747133315, COSV57159223, COSV57161033; called by muse, mutect2, varscan2
- NUGGC | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.123); catalogued as rs371363580, COSV58439272; called by muse, mutect2, varscan2
- NUP188 | c.1019G>C p.S340T | Missense Mutation (SNP) | VAF 281/662 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs376452007; called by muse, mutect2, varscan2
- NUP88 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563564141, COSV56702610, COSV56708095; called by muse, mutect2, varscan2
- OAZ3 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs768996444, COSV58617338; called by muse, mutect2, varscan2
- OBSCN | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 180/425 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV52779154; called by muse, mutect2, varscan2
- OPRD1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758135542; called by muse, mutect2, varscan2
- OR10A7 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs751420573, COSV58277829; called by muse, mutect2, varscan2
- OR13C4 | c.867dup p.M290Hfs*8 | Frame Shift Ins (INS) | VAF 54/154 reads (35%) | catalogued as rs765409530; called by mutect2, pindel, varscan2
- OR2D2 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100203819; called by muse, mutect2, varscan2
- OR2M3 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs777056408; called by muse, mutect2, varscan2
- OR4M1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 132/632 reads (21%) | catalogued as rs550760273, COSV60061725; called by muse, mutect2, varscan2
- OR51S1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs560546339, COSV59057342; called by muse, mutect2, varscan2
- OR5A1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs796662079, COSV57378244; called by muse, mutect2, varscan2
- OR5D18 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs775742265, COSV61737083; called by muse, mutect2, varscan2
- OR6Q1 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56932474; called by muse, mutect2, varscan2
- OR8J3 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1319314823; called by muse, mutect2
- OS9 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57784830, COSV99232899; called by muse, mutect2, varscan2
- OSBP2 | c.1887dup p.S630Lfs*79 | Frame Shift Ins (INS) | VAF 88/203 reads (43%) | catalogued as rs772802379; called by mutect2, varscan2
- OSGEP | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV99248005; called by muse, mutect2, varscan2
- OSR1 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 135/322 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs975152724, COSV99693546; called by muse, mutect2, varscan2
- OVCH2 | c.289A>G p.R97G | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV101491885; called by muse, mutect2, varscan2
- P4HA2 | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs776333817; called by muse, mutect2, varscan2
- PAN2 | c.2681A>G p.N894S (on ENST00000425394 / NM_001127460.3; = p.N890S on NM_014871.5) | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312591669; called by muse, mutect2, varscan2
- PARD3B | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202130832, COSV100593218, COSV62535877; called by muse, mutect2, varscan2
- PASD1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1464860454, COSV64855304; called by muse, mutect2, varscan2
- PBRM1 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56286391; called by muse, varscan2
- PCDH17 | c.1675del p.A559Rfs*11 | Frame Shift Del (DEL) | VAF 159/602 reads (26%) | catalogued as COSV64977233; called by mutect2, pindel, varscan2
- PCDH8 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 109/366 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393972914; called by muse, mutect2, varscan2
- PCDH8 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as COSV58812644; called by muse, mutect2, varscan2
- PCDHB7 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.83); catalogued as rs200476708; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 94/218 reads (43%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCID2 | c.818del p.K273Sfs*4 | Frame Shift Del (DEL) | VAF 80/405 reads (20%) | catalogued as rs760522684; called by mutect2, pindel, varscan2
- PCNT | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 258/644 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs370135350, COSV52451884; called by muse, mutect2, varscan2
- PCNX3 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1276445785, COSV63137088; called by muse, mutect2, varscan2
- PDE3A | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs748938027; called by muse, mutect2, varscan2
- PDE6G | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV100148699; called by muse, mutect2, varscan2
- PDGFD | c.640del p.I214Lfs*68 | Frame Shift Del (DEL) | VAF 103/308 reads (33%) | catalogued as rs1333395128; called by mutect2, pindel, varscan2
- PDGFRA | c.2394C>A p.F798L | Missense Mutation (SNP) | VAF 205/541 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57275539; called by muse, mutect2, varscan2
- PDHA2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54782458; called by muse, mutect2, varscan2
- PDK2 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99142895; called by muse, mutect2, varscan2
- PHLPP1 | c.4717C>T p.R1573W | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs915094142; called by muse, mutect2, varscan2
- PIAS1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 119/307 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51031504; called by muse, mutect2, varscan2
- PIGZ | c.1467dup p.T490Dfs*2 | Frame Shift Ins (INS) | VAF 50/160 reads (31%) | catalogued as rs759867499; called by mutect2, varscan2
- PITPNM3 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 233/623 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752293643, COSV52595119; called by muse, mutect2, varscan2
- PIWIL1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs538546986, COSV55350951, COSV99806980; called by muse, mutect2, varscan2
- PIWIL3 | c.1154A>G p.K385R | Missense Mutation (SNP) | VAF 179/440 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.065); catalogued as COSV59994898; called by muse, mutect2, varscan2
- PKD1 | c.11713-1G>T p.X3905_splice (on ENST00000262304 / NM_001009944.3; = p.X3904_splice on NM_000296.4) | Splice Site (SNP) | VAF 123/289 reads (43%) | catalogued as rs867092741, CS1313912; called by muse, mutect2, varscan2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 56/154 reads (36%) | catalogued as rs747170999; called by pindel, varscan2
- PLEC | c.7939G>A p.E2647K (on ENST00000322810 / NM_201380.4; = p.E2537K on NM_000445.5) | Missense Mutation (SNP) | VAF 285/666 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.67); catalogued as rs377605567; called by muse, mutect2, varscan2
- PLEKHA7 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753472835; called by muse, mutect2, varscan2
- PLXNA4 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 108/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1284623467; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 42/96 reads (44%) | catalogued as rs782076287; called by mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 54/152 reads (36%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PNMA3 | c.261del p.W89Gfs*3 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | catalogued as COSV64722654; called by mutect2, varscan2
- POC5 | c.1562A>G p.E521G (on ENST00000428202 / NM_001099271.2; = p.E496G on NM_152408.2) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408846041; called by muse, varscan2
- POLR3A | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 288/673 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs1180926052, COSV64931472; called by muse, mutect2, varscan2
- PPFIA1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV54134324; called by muse, mutect2
- PPM1D | c.1349dup p.L450Ffs*6 | Frame Shift Ins (INS) | VAF 74/210 reads (35%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPP1R8 | c.807del p.T270Hfs*34 (on ENST00000311772 / NM_014110.5; = p.T46Hfs*34 on NM_002713.4) | Frame Shift Del (DEL) | VAF 81/236 reads (34%) | catalogued as COSV52579842; called by mutect2, pindel, varscan2
- PPP4R3C | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs910971162; called by muse, mutect2, varscan2
- PPP6R1 | c.2515dup p.Q839Pfs*106 | Frame Shift Ins (INS) | VAF 62/160 reads (39%) | catalogued as rs550637760; called by mutect2, varscan2
- PRAMEF2 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 116/313 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV99535502; called by muse, mutect2, varscan2
- PRPF38B | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs921122274; called by muse, mutect2, varscan2
- PRR18 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs866289085; called by muse, mutect2, varscan2
- PRRC2C | c.1399C>T p.R467W (on ENST00000367742; = p.R465W on NM_015172.4) | Missense Mutation (SNP) | VAF 149/389 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281668603; called by muse, mutect2, varscan2
- PRSS55 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 95/237 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs765848146; called by muse, mutect2, varscan2
- PSMD2 | c.2495C>T p.T832M | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200846938; called by muse, mutect2, varscan2
- PTCHD4 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs746678221, COSV59780494; called by muse, mutect2, varscan2
- PTPN18 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 163/398 reads (41%) | catalogued as rs1393936540; called by muse, mutect2, varscan2
- PTPRS | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 207/536 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs200771602, COSV53637901; called by muse, mutect2, varscan2
- PTX4 | c.252G>T p.Q84H (on ENST00000447419 / NM_001328608.2; = p.Q79H on NM_001013658.1) | Missense Mutation (SNP) | VAF 136/369 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99560421; called by muse, mutect2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 72/204 reads (35%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- R3HDM4 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1246626354, COSV64293202; called by muse, mutect2, varscan2
- RAD54L | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 303/758 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100914848; called by muse, mutect2, varscan2
- RASAL2 | c.2684G>A p.R895H | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs561944165; called by muse, mutect2, varscan2
- RASSF8 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140972036; called by muse, mutect2, varscan2
- RB1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 122/521 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs776307088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBKS | c.922_923del p.Q308Vfs*38 | Frame Shift Del (DEL) | VAF 50/179 reads (28%) | catalogued as rs781204782; called by pindel, varscan2
- RBM20 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 175/425 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1362458012, COSV101051422; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 107/326 reads (33%) | catalogued as COSV100563010; called by mutect2, pindel, varscan2
- RECQL4 | c.2492A>G p.H831R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754324912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REEP5 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1415009098, COSV54842949; called by muse, mutect2, varscan2
- RETN | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 114/328 reads (35%) | catalogued as COSV55569148; called by muse, mutect2, varscan2
- RFPL4B | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV101480729; called by muse, mutect2, varscan2
- RFX6 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756030718, COSV60588807; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 118/284 reads (42%) | catalogued as rs760343057; called by mutect2, varscan2
- RNF213 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760160793; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 179/279 reads (64%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNFT2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs775396476; called by muse, mutect2, varscan2
- ROBO1 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1263628233; called by muse, mutect2, varscan2
- RP1L1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV66753808; called by muse, mutect2, varscan2
- RTKN | c.467G>T p.G156V (on ENST00000272430 / NM_001015055.2; = p.G143V on NM_033046.2) | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99269526; called by muse, mutect2, varscan2
- RYBP | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 149/396 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1382885623, COSV72180845; called by muse, mutect2, varscan2
- SALL3 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs906293497, COSV73305790; called by muse, mutect2, varscan2
- SAMD11 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs778084644; called by muse, mutect2, varscan2
- SAMM50 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as rs755487664; called by muse, mutect2, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 125/259 reads (48%) | catalogued as rs761606832; called by mutect2, varscan2
- SBNO2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 150/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323536; called by muse, varscan2
- SBSN | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766134876; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | catalogued as rs765136101; called by mutect2, varscan2
- SCNN1B | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140945152; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SCRN1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs775045104, COSV99620966; called by muse, mutect2, varscan2
- SDHB | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 218/565 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.939); catalogued as rs199948437, COSV64965419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.6475A>G p.R2159G | Missense Mutation (SNP) | VAF 204/526 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1182892356; called by muse, mutect2, varscan2
- SDR9C7 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as rs374434836; called by muse, mutect2, varscan2
- SEBOX | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs782660798; called by muse, mutect2, varscan2
- SEL1L | c.1110del p.G371Vfs*20 | Frame Shift Del (DEL) | VAF 44/94 reads (47%) | catalogued as COSV60921783; called by mutect2, varscan2
- SELL | c.1119del p.G374Afs*8 (on ENST00000650983; = p.G361Afs*8 on NM_000655.5) | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | catalogued as rs1421526852; called by pindel, varscan2
- SEMA3F | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 127/317 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50037126; called by muse, mutect2, varscan2
- SEMA6C | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 138/341 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs1266128628, COSV100501692; called by muse, mutect2, varscan2
- SEMG2 | c.493dup p.R165Kfs*9 | Frame Shift Ins (INS) | VAF 64/185 reads (35%) | catalogued as rs1281128483; called by mutect2, pindel, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs764980440, COSV58616367; called by mutect2, pindel, varscan2
- SERPINE1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 217/501 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs867364951; called by muse, mutect2, varscan2
- SERPINI1 | c.1029G>T p.E343D | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV55510300; called by muse, mutect2, varscan2
- SHANK2 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs782699631, COSV53589267, COSV99572189; called by muse, mutect2, varscan2
- SHPRH | c.4955G>T p.S1652I (on ENST00000275233 / NM_001042683.3; = p.S1656I on NM_173082.3) | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV51604278; called by muse, mutect2, varscan2
- SHROOM2 | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 206/508 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767591095; called by muse, mutect2, varscan2
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SKOR2 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs1365782843; called by muse, mutect2
- SLC16A6 | c.1320A>G p.A440= | Splice Region (SNP) | VAF 33/74 reads (45%) | catalogued as rs782484148; called by muse, mutect2, varscan2
- SLC19A1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772742675; called by muse, mutect2, varscan2
- SLC30A3 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1162915438; called by muse, mutect2, varscan2
- SLC35G4 | c.143del p.G48Afs*120 | Frame Shift Del (DEL) | VAF 94/284 reads (33%) | catalogued as rs751708818; called by mutect2, pindel, varscan2
- SLC45A1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 142/336 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775119911; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC4A3 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.493); catalogued as rs1254650443; called by muse, mutect2, varscan2
- SLC4A7 | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1161458423, COSV55394749; called by muse, mutect2, varscan2
- SLC4A9 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 225/602 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs756572727; called by muse, mutect2, varscan2
- SLC9A3 | c.2199del p.I734Sfs*68 | Frame Shift Del (DEL) | VAF 112/349 reads (32%) | catalogued as rs1193005485; called by mutect2, pindel, varscan2
- SLCO4C1 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs761404994; called by muse, mutect2, varscan2
- SLIT1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 153/385 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs201085723; called by muse, mutect2, varscan2
- SLIT3 | c.1479C>A p.S493R | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs573099201; called by muse, mutect2, varscan2
- SLK | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs140715399; called by muse, mutect2, varscan2
- SMO | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 217/550 reads (39%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as rs200751953, COSV50835094; called by muse, mutect2, varscan2
- SMPD3 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200140589, COSV54711420; called by muse, mutect2, varscan2
- SNPH | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); catalogued as rs754975513; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 57/176 reads (32%) | catalogued as rs768873484; called by mutect2, varscan2
- SOGA1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 161/362 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435382042, COSV52914054; called by muse, mutect2, varscan2
- SORCS1 | c.1427A>G p.K476R | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1450949270, COSV99549876; called by muse, mutect2, varscan2
- SOS1 | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 249/636 reads (39%) | catalogued as COSV67674007; called by muse, mutect2, varscan2
- SOX9 | c.773_774dup p.L259Pfs*21 | Frame Shift Ins (INS) | VAF 145/421 reads (34%) | catalogued as CI098477, COSV55424224; called by mutect2, pindel, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 62/211 reads (29%) | catalogued as rs771765677; called by mutect2, pindel, varscan2
- SPEN | c.10475C>T p.S3492F | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV65270811, COSV65272110; called by muse, mutect2, varscan2
- SPINT2 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 188/457 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as rs1370702137; called by muse, mutect2, varscan2
- SPON2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs916082660; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 94/250 reads (38%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPRY2 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761596736; called by muse, mutect2, varscan2
- SRCIN1 | c.3133C>T p.R1045W (on ENST00000621492; = p.R1011W on NM_025248.3) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1280191131; called by muse, mutect2, varscan2
- SRCIN1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs552981903; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as rs763130641; called by mutect2, varscan2
- SRRM1 | c.983C>A p.P328Q | Missense Mutation (SNP) | VAF 132/360 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs570634850; called by muse, mutect2, varscan2
- SRRM5 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 217/480 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1318643822, COSV56194441; called by muse, mutect2, varscan2
- SRSF1 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99365351; called by muse, mutect2, varscan2
- SSR2 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as rs773535812, COSV99828631; called by muse, mutect2, varscan2
- STAG3 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs775128180, COSV99444315; called by muse, mutect2, varscan2
- STAM | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 288/679 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV66351441; called by muse, mutect2, varscan2
- STK11IP | c.2956C>G p.P986A | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs748673563; called by muse, mutect2, varscan2
- STK17B | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55829842; called by muse, varscan2
- STON1 | c.793dup p.H265Pfs*20 | Frame Shift Ins (INS) | VAF 28/90 reads (31%) | catalogued as rs747498108; called by mutect2, pindel, varscan2
- SUN2 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs749230478, COSV53305031; called by muse, mutect2, varscan2
- SURF6 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs782465475; called by muse, mutect2, varscan2
- SVEP1 | c.9947C>T p.T3316M | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201866666; called by muse, mutect2, varscan2
- SYCE1L | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1266188546; called by muse, mutect2, varscan2
- SYNGAP1 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144778033; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAB1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 126/341 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs373883129; called by muse, mutect2, varscan2
- TACSTD2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 204/495 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV64667085; called by muse, mutect2, varscan2
- TAF4 | c.2086G>A p.V696M | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767742516, COSV53344057; called by muse, mutect2, varscan2
- TAF6 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59842516; called by muse, mutect2, varscan2
- TANC1 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs759435249, COSV55084015, COSV55098286; called by muse, mutect2
- TAOK3 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1019601490; called by muse, mutect2, varscan2
- TARS3 | c.1271dup p.L425Pfs*9 | Frame Shift Ins (INS) | VAF 39/133 reads (29%) | catalogued as rs1207173849; called by mutect2, pindel, varscan2
- TASP1 | c.1095A>C p.L365= | Splice Region (SNP) | VAF 52/118 reads (44%) | catalogued as rs747166003; called by muse, mutect2, varscan2
- TBC1D4 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774632711; called by muse, mutect2, varscan2
- TBX3 | c.805C>T p.R269W (on ENST00000257566 / NM_016569.4; = p.R249W on NM_005996.4) | Missense Mutation (SNP) | VAF 156/424 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1198837775, COSV57472745; called by muse, mutect2, varscan2
- TCF19 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565850915; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 74/159 reads (47%) | catalogued as rs748021112; called by mutect2, varscan2
- TCTE1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 153/364 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151164597, COSV65255558; called by muse, mutect2, varscan2
- TDP1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 186/452 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs113531329; called by muse, mutect2, varscan2
- TDRD5 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99677226; called by muse, mutect2, varscan2
- TECPR1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457116947, COSV65784318; called by muse, mutect2, varscan2
- TENM1 | c.4600T>C p.Y1534H | Missense Mutation (SNP) | VAF 118/294 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64431250; called by muse, mutect2, varscan2
- TENM3 | c.5548G>A p.V1850M | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as rs748357813; called by muse, mutect2, varscan2
- TGIF2LX | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 172/454 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs773693755, COSV99383199; called by muse, mutect2, varscan2
- TIGD3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 188/507 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV52887847; called by muse, mutect2, varscan2
- TLE3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as rs774554797, COSV58168716; called by muse, varscan2
- TMCC3 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as rs1303417409; called by muse, mutect2, varscan2
- TMEM132D | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs144267550, COSV67160505, COSV67160591, COSV67162685; called by muse, mutect2, varscan2
- TMEM145 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as rs1467739554, COSV52090596, COSV52095927; called by muse, mutect2, varscan2
- TMEM175 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755453723, COSV53278086; called by muse, mutect2, varscan2
- TMEM267 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 174/436 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67992629; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 58/148 reads (39%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS7 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 156/426 reads (37%) | catalogued as rs753285417; called by muse, mutect2, varscan2
- TNIP1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340667932; called by muse, varscan2
- TNK2 | c.1482del p.D495Tfs*3 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as rs750898925, COSV100361004; called by mutect2, pindel, varscan2
- TOGARAM1 | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs376348966; called by muse, mutect2, varscan2
- TOP2B | c.4321del p.S1441Vfs*41 (on ENST00000264331 / NM_001330700.2; = p.S1436Vfs*41 on NM_001068.3) | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs1293862281; called by mutect2, pindel, varscan2
- TOX2 | c.730C>T p.P244S (on ENST00000358131 / NM_001098798.2; = p.P193S on NM_032883.3) | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs1186188793; called by muse, mutect2, varscan2
- TPP2 | c.3394G>A p.A1132T | Missense Mutation (SNP) | VAF 147/526 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs1329723822; called by muse, mutect2, varscan2
- TPR | c.3955G>A p.G1319S | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs779907740; called by muse, mutect2, varscan2
- TRAF5 | c.1368del p.S457Hfs*26 | Frame Shift Del (DEL) | VAF 66/194 reads (34%) | catalogued as COSV99807703; called by mutect2, pindel, varscan2
- TRAFD1 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as rs115008525; called by muse, mutect2, varscan2
- TRAPPC11 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs577423330, COSV58216838; called by muse, mutect2, varscan2
- TRIM41 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 228/517 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as rs753810828; called by muse, mutect2, varscan2
- TRIM45 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as rs145680896; called by muse, mutect2, varscan2
- TRIM67 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 139/384 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100792225; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 64/180 reads (36%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIP12 | c.4417C>A p.L1473I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52259212; called by muse, mutect2, varscan2
- TRPC7 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs756214253; called by muse, mutect2, varscan2
- TRPM4 | c.3462G>A p.K1154= | Splice Region (SNP) | VAF 116/328 reads (35%) | catalogued as rs771732356; called by muse, mutect2, varscan2
- TRRAP | c.4802G>A p.R1601Q (on ENST00000359863 / NM_001244580.1; = p.R1583Q on NM_003496.3) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as rs782247298; called by muse, mutect2, varscan2
- TTBK2 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs371341038, COSV99141078; called by muse, mutect2, varscan2
- TTC21B | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 166/428 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs781486283, COSV54632170; called by muse, mutect2, varscan2
- TTC27 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200122950; called by muse, mutect2, varscan2
- TTN | c.61519G>A p.A20507T (on ENST00000591111; = p.A13083T on NM_003319.4) | Missense Mutation (SNP) | VAF 182/488 reads (37%) | PolyPhen benign (0.232); catalogued as rs794727433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.2506G>A p.G836S (on ENST00000591111; = p.G790S on NM_003319.4) | Missense Mutation (SNP) | VAF 77/178 reads (43%) | PolyPhen probably damaging (0.962); catalogued as rs751157908, COSV59988553, COSV60007599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3D | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs530707778, COSV58311137; called by muse, mutect2, varscan2
- TULP4 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV65577457; called by muse, mutect2, varscan2
- UBE4B | c.1329del p.A444Hfs*14 (on ENST00000343090 / NM_001105562.3; = p.A315Hfs*14 on NM_006048.5) | Frame Shift Del (DEL) | VAF 46/108 reads (43%) | catalogued as rs758215455, COSV53529804; called by mutect2, varscan2
- UBQLN3 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs756923573; called by muse, mutect2, varscan2
- UCN3 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs370726908, COSV100991671; called by muse, mutect2, varscan2
- UGCG | c.1094del p.L365Cfs*9 | Frame Shift Del (DEL) | VAF 65/209 reads (31%) | catalogued as rs1243652090; called by mutect2, pindel, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 96/233 reads (41%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UHRF1BP1L | c.3691C>T p.R1231W | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs767522996; called by muse, mutect2, varscan2
- UNC13D | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 151/442 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776737156, CM112830, COSV52884054; called by muse, mutect2, varscan2
- UNC5B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs753370821; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 39/173 reads (23%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.15355C>T p.R5119W | Missense Mutation (SNP) | VAF 185/421 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs767137840, COSV56391560; called by muse, mutect2, varscan2
- USP13 | c.1896dup p.I633Hfs*5 | Frame Shift Ins (INS) | VAF 70/168 reads (42%) | catalogued as rs780272979; called by mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 72/192 reads (38%) | catalogued as rs749830910; called by mutect2, varscan2
- USP35 | c.2290C>A p.L764M | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as rs375971115; called by muse, mutect2, varscan2
- UTP14C | c.311dup p.Q105Afs*4 | Frame Shift Ins (INS) | VAF 320/1274 reads (25%) | catalogued as rs1175995992; called by mutect2, varscan2
- UTS2R | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 117/278 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs754369727; called by muse, mutect2, varscan2
- VCAN | c.2999C>A p.P1000H | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs761598424; called by muse, mutect2, varscan2
- VPS13B | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 151/377 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs773472945, COSV62020498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765547105, COSV62145591; called by muse, mutect2, varscan2
- VPS13C | c.4429del p.I1477Lfs*24 (on ENST00000644861 / NM_020821.3; = p.I1434Lfs*24 on NM_017684.5) | Frame Shift Del (DEL) | VAF 38/88 reads (43%) | catalogued as rs756149444; called by mutect2, varscan2
- VSTM2L | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1451937759; called by muse, mutect2, varscan2
- WDR49 | c.1821del p.K607Nfs*9 (on ENST00000308378 / NM_001366158.1; = p.K948Nfs*9 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs755423544; called by mutect2, varscan2
- WDR70 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 109/309 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs765801273, COSV54284222; called by muse, mutect2, varscan2
- WDR81 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as rs1439677993, COSV58486177; called by muse, mutect2, varscan2
- WDR90 | c.3362G>A p.R1121Q | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as rs754480122; called by muse, mutect2, varscan2
- WDR90 | c.3983C>T p.T1328M | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.337); catalogued as rs761884544, COSV53469911; called by muse, mutect2, varscan2
- WIPF2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765209297, COSV100063525, COSV100063743; called by muse, mutect2, varscan2
- WNK1 | c.2263G>A p.V755M (on ENST00000315939 / NM_018979.4; = p.V754M on NM_014823.3) | Missense Mutation (SNP) | VAF 196/482 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as rs1444380006; called by muse, varscan2
- WTIP | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV54328243; called by muse, mutect2, varscan2
- XPO4 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 75/305 reads (25%) | catalogued as COSV99688362; called by muse, mutect2, varscan2
- XYLT2 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50017497; called by muse, mutect2, varscan2
- ZAP70 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs1332610325; called by muse, mutect2, varscan2
- ZBTB7B | c.509C>T p.T170M (on ENST00000292176; = p.T204M on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/279 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs761967201; called by muse, mutect2, varscan2
- ZFHX3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 117/283 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs779915209; called by muse, mutect2, varscan2
- ZIC3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 212/547 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54972605; called by muse, mutect2, varscan2
- ZMIZ2 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1405506739, COSV54807197; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 142/232 reads (61%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF140 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as rs1446770586; called by muse, mutect2, varscan2
- ZNF142 | c.2030G>A p.R677Q (on ENST00000411696 / NM_001379660.1; = p.R477Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs759292993, COSV101376949; called by muse, mutect2, varscan2
- ZNF16 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs752265890, COSV52763616; called by muse, mutect2, varscan2
- ZNF174 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 191/527 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as COSV51902619; called by muse, mutect2, varscan2
- ZNF180 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 112/236 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs201078626; called by muse, mutect2, varscan2
- ZNF180 | c.208-3del | Splice Region (DEL) | VAF 109/342 reads (32%) | catalogued as rs1568425500; called by mutect2, pindel, varscan2
- ZNF2 | c.287del p.N96Tfs*29 | Frame Shift Del (DEL) | VAF 23/48 reads (48%) | catalogued as COSV54638492; called by mutect2, pindel, varscan2
- ZNF292 | c.7032G>T p.K2344N | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.941); catalogued as COSV60536211; called by muse, mutect2, varscan2
- ZNF346 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99993213; called by muse, mutect2, varscan2
- ZNF439 | c.972dup p.L325Tfs*3 | Frame Shift Ins (INS) | VAF 91/268 reads (34%) | catalogued as rs1313557565; called by mutect2, pindel, varscan2
- ZNF45 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54192846; called by muse, mutect2, varscan2
- ZNF486 | c.607del p.I203Lfs*28 | Frame Shift Del (DEL) | VAF 77/194 reads (40%) | catalogued as rs1555718177; called by mutect2, pindel, varscan2
- ZNF572 | c.18dup p.L7Tfs*7 | Frame Shift Ins (INS) | VAF 48/146 reads (33%) | catalogued as rs769734933; called by mutect2, varscan2
- ZNF592 | c.1879_1881del p.F627del | In Frame Del (DEL) | VAF 278/786 reads (35%) | catalogued as rs1250559095; called by pindel, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 104/280 reads (37%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF684 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.299); catalogued as COSV65519756; called by muse, mutect2, varscan2
- ZNF707 | c.764C>T p.T255I | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs781882112; called by muse, mutect2, varscan2
- ZNF71 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 146/361 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as rs562690323, COSV60150559; called by muse, mutect2, varscan2
- ZNRF4 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs201142539, COSV55773524; called by muse, mutect2, varscan2
- ZSCAN20 | c.2327G>A p.S776N | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs749010323; called by muse, mutect2, varscan2
- A2M | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- AATF | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 52/151 reads (34%) | called by mutect2, pindel, varscan2
- ABCA2 | c.5278-1G>T p.X1760_splice (on ENST00000614293; = p.X1730_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 105/247 reads (43%) | called by muse, mutect2, varscan2
- ABCA4 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 253/667 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ABCD1 | c.956T>A p.L319H | Missense Mutation (SNP) | VAF 252/632 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ABCD2 | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSF2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 134/311 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ACSF3 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVR2A | c.1156_1159del p.D386Cfs*6 | Frame Shift Del (DEL) | VAF 54/188 reads (29%) | called by pindel, varscan2
- ADAM10 | c.2212C>T p.R738* | Nonsense Mutation (SNP) | VAF 259/669 reads (39%) | called by muse, mutect2, varscan2
- ADAM28 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ADAMTS9 | c.2661G>A p.W887* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.263del p.P88Qfs*122 | Frame Shift Del (DEL) | VAF 69/202 reads (34%) | called by mutect2, pindel, varscan2
- ADCK5 | c.1295T>C p.M432T | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ADCY1 | c.1492del p.R498Gfs*2 | Frame Shift Del (DEL) | VAF 102/233 reads (44%) | called by mutect2, pindel, varscan2
- ADCY4 | c.714_715del p.E238Dfs*21 | Frame Shift Del (DEL) | VAF 90/334 reads (27%) | called by pindel, varscan2
- ADCY7 | c.2020C>A p.L674M | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ADGRA1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ADGRG4 | c.1027dup p.T343Nfs*16 | Frame Shift Ins (INS) | VAF 99/250 reads (40%) | called by mutect2, varscan2
- ADGRV1 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADTRP | c.205del p.R69Efs*11 | Frame Shift Del (DEL) | VAF 75/252 reads (30%) | called by mutect2, pindel, varscan2
- AGAP3 | c.1820G>A p.S607N (on ENST00000622464; = p.S643N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.5309T>C p.L1770P | Missense Mutation (SNP) | VAF 303/721 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AL662899.2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALLC | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALX4 | c.1016del p.P339Lfs*12 | Frame Shift Del (DEL) | VAF 124/391 reads (32%) | called by mutect2, pindel, varscan2
- AMER1 | c.545G>C p.S182T | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- AMER2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- AMER3 | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 105/280 reads (38%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1958C>A p.P653Q | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKFN1 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ANKRD17 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ANKRD24 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 157/355 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD33B | c.1091del p.G364Afs*212 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- ANKRD65 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKS4B | c.1100_1101dup p.Q368Sfs*5 | Frame Shift Ins (INS) | VAF 50/122 reads (41%) | called by mutect2, varscan2
- AP1G2 | c.2138G>A p.C713Y | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- AP2B1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- AP3S1 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- APBB2 | c.1641G>T p.K547N (on ENST00000295974 / NM_001166050.2; = p.K548N on NM_004307.2) | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- APC2 | c.5935C>A p.L1979I | Missense Mutation (SNP) | VAF 131/320 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AR | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 142/388 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP20 | c.48del p.R17Afs*5 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.5204T>C p.V1735A (on ENST00000310343 / NM_001378025.1; = p.V1386A on NM_014715.4) | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP32 | c.360T>G p.C120W | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF15 | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 58/120 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF37 | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ARHGEF39 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.035); called by muse, varscan2
- ARID1A | c.2828C>A p.P943H | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARID1B | c.3738del p.Y1247Tfs*5 | Frame Shift Del (DEL) | VAF 114/333 reads (34%) | called by mutect2, pindel, varscan2
- ARMC2 | c.672G>T p.G224= | Splice Region (SNP) | VAF 76/144 reads (53%) | called by muse, mutect2, varscan2
- ARNTL2 | c.1288dup p.I430Nfs*24 | Frame Shift Ins (INS) | VAF 27/71 reads (38%) | called by mutect2, pindel, varscan2
1,330 further variants in this file (613 protein-altering or splice-affecting, 421 silent, 296 other) are not listed here.
